Gene-level copy-number profile of tumor specimen TCGA-DX-AB2F-01A from TCGA case TCGA-DX-AB2F, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 76.2 years (27,840 days).
Specimen TCGA-DX-AB2F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.0e1347f9-53a6-4608-9da5-ce4934c8cdfb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89f1b006-8283-4e91-a4c5-fa9921b4e309

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 15; copy number 2: 6,656; copy number 3: 16,282; copy number 4: 31,241; copy number 5: 2,312; copy number 6: 1,287; copy number 7: 567; copy number 8: 84; copy number 9: 431; copy number 10: 231; copy number 11: 122; copy number 12: 56; copy number 13: 32; copy number 14: 3; copy number 15: 113; copy number 16: 22; copy number 18: 18; copy number 19: 7; copy number 20: 46; copy number 21: 17; copy number 23: 1; copy number 25: 5; copy number 26: 20; copy number 27: 19; copy number 28: 1; copy number 29: 1; copy number 30: 7; copy number 31: 2; copy number 34: 10; copy number 35: 4; copy number 36: 1; copy number 42: 2; copy number 43: 1; copy number 44: 2; copy number 45: 26; copy number 46: 5; copy number 48: 37; copy number 54: 16; copy number 55: 2; copy number 63: 7; copy number 67: 1; copy number 69: 4; copy number 76: 9; copy number 79: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2F-01A-11D-A386-01): tumor purity 0.68, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–5,509,126, 73 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,265 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:118,088,452–118,994,660, 6 genes, copy number 9: INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1.
- chr2:129,966,592–130,330,285, 40 genes, copy number 10: RAB6C-AS1, RAB6C, AC079776.3, AC079776.4, AC079776.2, AC079776.1, ARHGAP42P2, FAR2P1, AC018865.2, KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P, MED15P9, CCDC74B, SMPD4, MZT2B, TUBA3E, AC018804.1, RHOQP3, NOC2LP1, AC134915.1, MED15P5, MTND1P29, MTND2P22, MTCO1P7, MTCO2P7, MTATP6P7, MTCO3P7, MTND3P15, AC068137.1, MTND4P27, MTND5P29, MTND6P8, MTCYBP8, RPL19P4, TEKT4P3, AC132479.1.
- chr2:130,836,914–131,767,404, 56 genes, copy number 10 (within-gene range 2–10): ARHGEF4, AC112786.1, AC112786.2, SMIM39, FAM168B, PLEKHB2, NEK2P4, AC009477.1, NF1P8, AC131180.1, MED15P8, POTEE, RNU6-127P, FAR2P4, KLF2P4, AC073869.5, ARHGAP42P1, AC073869.7, SSBP3P2, RAB6D, AC073869.3, MTCYBP10, MTND6P10, MTND5P23, MTND4P21, AC073869.4, MTND3P18, MTCO3P18, MTATP6P4, MTCO2P18, MTCO1P18, MTND2P18, MTND1P26, MED15P3, AC073869.2, LINC01120, AC073869.6, GNAQP1, NOC2LP2, RHOQP2, AC073869.1, MZT2A, TUBA3D, MIR4784, SMPD4BP, CCDC74A, MED15P4, AC093838.1, POTEKP, RNU6-617P, LINC01087, GRAMD4P8, C2orf27A, AC093838.2, NBEAP2, TOMM40P4.
- chr2:139,824,896–143,768,352, 31 genes, copy number 10–20 (within-gene range 8–20): AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3, AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1.
- chr2:155,089,439–157,876,330, 29 genes, copy number 12 (within-gene range 2–12): RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, AC073225.1, LINC01876, HEBP2P1, AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1, CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1.
- chr6:113,531,118–113,581,947, 2 genes, copy number 9: AL513123.1, RPS27AP11.
- chr6:117,048,670–119,391,829, 35 genes, copy number 10–12 (within-gene range 5–12): RPS29P13, RNA5SP214, Z98880.1, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P, GOPC, NEPNP, NUS1, SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1.
- chr6:123,803,865–124,825,640, 2 genes, copy number 10 (within-gene range 3–10): NKAIN2, AL354936.1.
- chr6:127,438,406–139,291,998, 209 genes, copy number 9–15 (within-gene range 3–15) (broad region; genes not listed).
- chr6:139,338,018–139,374,648, 2 genes, copy number 15: AL592429.1, CITED2.
- chr6:140,575,788–144,853,034, 57 genes, copy number 10–11 (within-gene range 4–11): AL035446.2, MIR4465, RPS3AP24, AL035446.1, AL357084.1, AL357080.1, AL355596.2, AL355596.1, RN7SKP106, RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1.
- chr6:146,543,833–151,358,559, 101 genes, copy number 11–26 (within-gene range 3–26) (broad region; genes not listed).
- chr6:152,959,359–153,131,282, 5 genes, copy number 11: AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17.
- chr6:153,665,707–155,655,026, 34 genes, copy number 10–13: MTCO2P31, AL603908.1, MTATP6P31, MTCO3P31, MTND3P20, MTND4LP20, MTND4P13, RNU6-896P, HMGB3P19, OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1, AL591499.1, SCAF8, RNU6-824P, TIAM2, AL121952.1, MIR1273C, U8, AL136228.1, AL596202.1, TFB1M, CLDN20, AL031773.1, NOX3, RNU7-152P.
- chr6:156,493,226–159,662,627, 64 genes, copy number 13–18 (within-gene range 5–18) (broad region; genes not listed).
- chr6:164,084,023–168,673,445, 87 genes, copy number 15–34 (within-gene range 12–34) (broad region; genes not listed).
- chr12:46,682,071–46,682,713, 1 gene, copy number 54: MARK3P1.
- chr12:57,229,498–57,296,484, 5 genes, copy number 27: AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1.
- chr12:57,591,174–57,846,729, 28 genes, copy number 48 (within-gene range 3–48): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:58,544,124–58,920,504, 3 genes, copy number 34–36 (within-gene range 3–36): AC020637.1, LINC02388, LRIG3.
- chr12:61,600,067–62,417,431, 12 genes, copy number 10–44 (within-gene range 3–44): DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:63,558,913–63,795,718, 4 genes, copy number 26 (within-gene range 3–26): DPY19L2, AC084357.2, AC027667.1, AC084357.3.
- chr12:65,169,583–65,248,355, 2 genes, copy number 42 (within-gene range 3–42): LEMD3, AC026124.2.
- chr12:65,758,020–65,966,291, 5 genes, copy number 9 (within-gene range 3–9): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,950,754–68,234,686, 21 genes, copy number 14–67 (within-gene range 3–67): AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:68,610,855–69,224,242, 19 genes, copy number 11–76: RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1.
- chr12:69,449,470–70,243,379, 15 genes, copy number 54 (within-gene range 3–54): LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821.
- chr12:70,638,073–71,927,248, 22 genes, copy number 21–69 (within-gene range 4–69): PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:73,115,957–73,679,296, 5 genes, copy number 18–79: AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P.
- chr12:74,248,637–74,664,141, 7 genes, copy number 30: AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1.
- chr12:75,020,969–75,209,839, 2 genes, copy number 27 (within-gene range 3–27): AC073525.1, KCNC2.
- chr12:76,562,294–76,757,914, 7 genes, copy number 63 (within-gene range 3–63): AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1.
- chr12:77,775,783–78,359,746, 4 genes, copy number 46: AC138331.1, AC073571.1, PRXL2AP1, LINC02424.
- chr12:84,147,304–84,449,878, 4 genes, copy number 35: AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr12:95,387,890–96,979,629, 34 genes, copy number 18–45: AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA.
- chr12:99,647,753–100,199,783, 11 genes, copy number 10–31: FAM71C, AC078916.1, RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827.
- chr15:84,980,440–85,330,334, 9 genes, copy number 9–21 (within-gene range 4–21): PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3.
- chr19:94,062–3,538,334, 210 genes, copy number 9–10 (within-gene range 4–10) (broad region; genes not listed).
- chr19:56,354,493–56,848,556, 30 genes, copy number 9: AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835, AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1.
- chr20:61,953,469–62,700,480, 40 genes, copy number 20: TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
